Somatic mutation profile of tumor specimen 0DD0A9 from CCDI case PBBNEP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 17.4 years (6,361 days).
Specimen 0DD0A9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d7f3eb0-9e20-4354-a2c7-412af381297f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD09J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12a3f465-6dff-4db8-9dd4-600cfe1876e4

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 104/757 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.027); catalogued as rs749826586, COSV50503734; called by muse, mutect2, varscan2
- LOXHD1 | c.3511A>G p.K1171E | Missense Mutation (SNP) | VAF 28/808 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1400810655; called by muse, mutect2
- CD22 | c.1907G>A p.S636N | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDN8 | c.278T>A p.L93* | Nonsense Mutation (SNP) | VAF 58/292 reads (20%) | called by muse, mutect2, varscan2
- COL2A1 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 276/596 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H2AC11 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 189/553 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TM4SF19 | c.572_585del p.V191Dfs*33 | Frame Shift Del (DEL) | VAF 148/398 reads (37%) | called by mutect2, varscan2
- TMEM52B | c.268G>T p.A90S (on ENST00000381923 / NM_001079815.1; = p.A70S on NM_153022.4) | Missense Mutation (SNP) | VAF 37/669 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2
- ZAN | c.8411C>T p.T2804I | Missense Mutation (SNP) | VAF 225/508 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GJA5 | c.162T>C p.C54= | Silent (SNP) | VAF 170/329 reads (52%) | called by muse, mutect2, varscan2
- KDM2B | c.2622C>T p.N874= | Silent (SNP) | VAF 122/365 reads (33%) | catalogued as rs782132703, COSV65640792; called by muse, mutect2, varscan2
- PEAK3 | c.1260C>T p.L420= | Silent (SNP) | VAF 132/336 reads (39%) | called by muse, varscan2
- COL21A1 | c.1812+9973G>C | Intron (SNP) | VAF 18/498 reads (4%) | called by muse, mutect2
- QTRT1 | c.785+45G>A | Intron (SNP) | VAF 97/331 reads (29%) | called by muse, mutect2, varscan2
